Somatic mutation profile of tumor specimen TCGA-32-2494-01A (aliquot TCGA-32-2494-01A-01D-1353-08) from TCGA case TCGA-32-2494, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 58.0 years (21,198 days).
Specimen TCGA-32-2494-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4af4316-4453-40e9-8176-041950968adc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-32-2494-10A (Blood Derived Normal), aliquot TCGA-32-2494-10A-01D-1353-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/495ce163-b509-443b-b0f9-5c8881d7adcc

The open-access MAF lists 59 somatic variants for this specimen: 38 protein-altering or splice-affecting, 16 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 16, 5'UTR 3, Frame Shift Del 2, Nonsense Mutation 1, Frame Shift Ins 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRG4 | c.6821C>T p.S2274L | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1272460149, COSV54956046; called by muse, mutect2, varscan2
- ATP11C | c.916G>T p.A306S | Missense Mutation (SNP) | VAF 67/234 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.977); catalogued as COSV59573820; called by muse, mutect2, varscan2
- C3orf20 | c.2081A>C p.D694A | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53789182; called by muse, mutect2, varscan2
- CCNB3 | c.2150G>T p.S717I | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.025); catalogued as rs781872733, COSV52079445; called by muse, mutect2, varscan2
- CKAP2L | c.739G>A p.G247R | Missense Mutation (SNP) | VAF 56/218 reads (26%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV56698161; called by muse, mutect2, varscan2
- CLCNKB | c.1087G>A p.D363N | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs779798035, COSV65159471; called by muse, mutect2, varscan2
- DDIAS | c.201_204del p.K68Cfs*11 | Frame Shift Del (DEL) | VAF 34/146 reads (23%) | catalogued as rs1278882528; called by pindel, varscan2
- DMRTB1 | c.73G>T p.G25* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as COSV65114000; called by muse, mutect2, varscan2
- FNDC1 | c.4999G>A p.V1667M | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (1); PolyPhen possibly damaging (0.468); catalogued as COSV51947512; called by muse, mutect2, varscan2
- FSD1 | c.1114G>A p.G372S | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as rs1279877532, COSV55698771; called by muse, mutect2, varscan2
- GDF10 | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.928); catalogued as rs1555207467; called by muse, mutect2, varscan2
- HEATR5A | c.3854G>A p.S1285N | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.079); catalogued as COSV66345423; called by muse, mutect2, varscan2
- HIVEP1 | c.1465G>A p.V489I | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as rs199639832, COSV65104911; called by muse, mutect2, varscan2
- HMCN1 | c.13844A>T p.N4615I | Missense Mutation (SNP) | VAF 48/198 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV54939565; called by muse, mutect2, varscan2
- HOXA13 | c.761T>C p.V254A | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.574); catalogued as COSV56084246; called by muse, mutect2, varscan2
- HSPG2 | c.10069C>T p.P3357S | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.816); catalogued as rs759825090, COSV65934028; called by muse, varscan2
- KCNK13 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs769579882, COSV56410859; called by muse, mutect2, varscan2
- KRT12 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as rs368116028; called by muse, mutect2, varscan2
- LAMC1 | c.4805A>G p.N1602S | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as COSV51175678; called by muse, mutect2, varscan2
- LYN | c.8G>A p.C3Y | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV72923704; called by muse, mutect2, varscan2
- MN1 | c.2993C>T p.P998L | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.211); catalogued as COSV100180086; called by muse, mutect2, varscan2
- MYO3A | c.742C>T p.P248S | Missense Mutation (SNP) | VAF 47/161 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV56348338; called by muse, mutect2, varscan2
- NR3C2 | c.1818T>G p.C606W | Missense Mutation (SNP) | VAF 47/184 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60999610; called by muse, mutect2, varscan2
- OR13C3 | c.832G>T p.V278L | Missense Mutation (SNP) | VAF 47/290 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66166257; called by muse, mutect2, varscan2
- PIWIL1 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.511); catalogued as rs772560236, COSV55351755; called by muse, mutect2, varscan2
- SBF1 | c.5182G>A p.A1728T | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.023); catalogued as rs747746536, COSV53298190; called by muse, mutect2, varscan2
- SCAMP2 | c.781A>C p.I261L | Missense Mutation (SNP) | VAF 92/286 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV51513348; called by muse, mutect2, varscan2
- SIM1 | c.176G>A p.G59E | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53496546; called by muse, mutect2, varscan2
- SLC29A2 | c.1058G>T p.W353L | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100237029, COSV60804126; called by muse, mutect2, varscan2
- SLC29A2 | c.1057T>G p.W353G | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100237191; called by muse, mutect2, varscan2
- SNX14 | c.824C>G p.S275C (on ENST00000314673 / NM_001350535.1; = p.S231C on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV59014982, COSV59016161, COSV59016906; called by muse, mutect2, varscan2
- TADA2A | c.1079G>A p.R360Q | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.491); catalogued as rs369901141; called by muse, mutect2, varscan2
- TKTL1 | c.928G>A p.V310I | Missense Mutation (SNP) | VAF 56/229 reads (24%) | SIFT tolerated (0.84); PolyPhen benign (0.012); catalogued as rs782811019, COSV54211970; called by muse, mutect2, varscan2
- VEZT | c.707C>T p.T236I | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54144941; called by muse, mutect2, varscan2
- VPS8 | c.178C>G p.P60A | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54996149; called by muse, mutect2, varscan2
- AFP | c.1360del p.M454Wfs*37 | Frame Shift Del (DEL) | VAF 20/89 reads (22%) | called by mutect2, pindel, varscan2
- ANO2 | c.1991G>T p.C664F (on ENST00000356134 / NM_001278597.3; = p.C668F on NM_001278596.3) | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.485); called by muse, mutect2
- ARHGAP29 | c.1943dup p.C649Vfs*48 | Frame Shift Ins (INS) | VAF 25/97 reads (26%) | called by mutect2, pindel, varscan2
- ACAP2 | c.2025G>A p.R675= | Silent (SNP) | VAF 35/144 reads (24%) | catalogued as rs892396623, COSV58755654; called by muse, mutect2, varscan2
- AWAT2 | c.255T>C p.Y85= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs778051530, COSV52144510; called by muse, mutect2, varscan2
- CDRT15 | c.336C>T p.A112= | Silent (SNP) | VAF 11/80 reads (14%) | catalogued as rs1251029470, COSV69755773; called by muse, mutect2
- CILP | c.975C>T p.S325= | Silent (SNP) | VAF 65/206 reads (32%) | catalogued as rs193195655, COSV56026743; called by muse, mutect2, varscan2
- CMYA5 | c.11079A>C p.A3693= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as COSV101484288; called by muse, mutect2, varscan2
- CNTN6 | c.669G>T p.G223= | Silent (SNP) | VAF 52/215 reads (24%) | catalogued as rs933361582, COSV63188780; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.63A>G p.V21= | Silent (SNP) | VAF 41/444 reads (9%) | catalogued as rs768811237; called by muse, mutect2
- LHCGR | c.1455G>T p.L485= | Silent (SNP) | VAF 42/126 reads (33%) | catalogued as COSV54302807; called by muse, mutect2, varscan2
- MAD1L1 | c.726G>A p.V242= | Silent (SNP) | VAF 29/109 reads (27%) | catalogued as COSV56247028; called by muse, mutect2, varscan2
- MUC3A | c.8529A>T p.S2843= | Silent (SNP) | VAF 81/421 reads (19%) | catalogued as COSV100113917; called by muse, mutect2, varscan2
- MYRIP | c.1239G>A p.R413= | Silent (SNP) | VAF 52/168 reads (31%) | catalogued as COSV56880962; called by muse, mutect2, varscan2
- RBL2 | c.1884G>T p.L628= | Silent (SNP) | VAF 83/374 reads (22%) | catalogued as COSV50887593; called by muse, mutect2, varscan2
- SERPINB10 | c.357G>A p.T119= | Silent (SNP) | VAF 36/135 reads (27%) | catalogued as rs201911253, COSV53075305; called by muse, mutect2, varscan2
- SLC25A14 | c.519A>G p.G173= | Silent (SNP) | VAF 76/246 reads (31%) | catalogued as COSV54420101; called by muse, mutect2, varscan2
- TRPV6 | c.366G>A p.A122= | Silent (SNP) | VAF 85/380 reads (22%) | catalogued as rs145875993; called by muse, mutect2, varscan2
- ZC3H12B | c.1161G>A p.S387= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs1193698106, COSV59051369; called by muse, mutect2, varscan2
- AC073310.1 | n.300G>A | RNA (SNP) | VAF 108/502 reads (22%) | called by muse, mutect2, varscan2
- ALDH3A1 | c.-36G>A | 5'UTR (SNP) | VAF 7/34 reads (21%) | catalogued as COSV99856012; called by muse, mutect2, varscan2
- H2BC21 | c.-2C>G | 5'UTR (SNP) | VAF 18/76 reads (24%) | catalogued as COSV100479822, COSV100480089; called by muse, mutect2, varscan2
- RPS11 | c.224-146G>A | Intron (SNP) | VAF 69/291 reads (24%) | catalogued as COSV99569443; called by muse, mutect2, varscan2
- TAF1 | c.-53C>T | 5'UTR (SNP) | VAF 31/129 reads (24%) | catalogued as rs765758474, COSV52124434; called by muse, mutect2, varscan2
